Somatic mutation profile of tumor specimen MMRF_2729_1_BM_CD138pos (aliquot MMRF_2729_1_BM_CD138pos_T1_KHS5U_L14870) from MMRF case MMRF_2729, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow.
Specimen MMRF_2729_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d15aefd4-7c07-4a6d-b7c3-2f417bdac071.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2729_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2729_1_PB_WBC_C3_KHS5U_L14871; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d341226d-46e9-459e-9dd5-2655d8dc216b

The open-access MAF lists 96 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 18, Silent 11, Intron 9, 5'UTR 8, 5'Flank 2, Frame Shift Del 2, RNA 2, Nonsense Mutation 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H3C2 | c.153G>C p.E51D | Missense Mutation (SNP) | VAF 99/226 reads (44%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.03); PolyPhen benign (0.059); catalogued as COSV52518005, COSV99451705; called by muse, mutect2, varscan2
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 108/297 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIM1 | c.111G>C p.Q37H | Missense Mutation (SNP) | VAF 52/141 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs751073896, COSV65165508, COSV65166397, COSV65166671; called by muse, mutect2, varscan2
- PROK2 | c.297dup p.G100Wfs*22 (on ENST00000295619 / NM_001126128.2; = p.G79Wfs*22 on NM_021935.4) | Frame Shift Ins (INS) | VAF 44/133 reads (33%) | catalogued as rs768413190; ClinVar: likely pathogenic; called by mutect2, pindel, varscan2
- ADGRV1 | c.14875G>A p.V4959I | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs372932617; called by muse, mutect2, varscan2
- AK6 | c.7C>T p.L3F | Missense Mutation (SNP) | VAF 34/66 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs1327105532; called by muse, mutect2, varscan2
- C1S | c.355C>T p.R119C | Missense Mutation (SNP) | VAF 84/202 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1265716590, COSV61071187; called by muse, mutect2, varscan2
- CDK16 | c.1369C>A p.P457T | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs1414307923; called by muse, mutect2, varscan2
- CILP2 | c.1648G>A p.E550K | Missense Mutation (SNP) | VAF 111/219 reads (51%) | SIFT tolerated (0.06); PolyPhen benign (0.322); catalogued as COSV52274801, COSV52281504; called by muse, mutect2, varscan2
- DNAJB11 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.201); catalogued as rs761576121; called by muse, mutect2
- DUSP2 | c.253C>G p.L85V | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.103); catalogued as COSV56620804; called by muse, mutect2, varscan2
- EEF1A1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.239); catalogued as COSV58548980; called by muse, mutect2, varscan2
- FOXG1 | c.757A>T p.N253Y | Missense Mutation (SNP) | VAF 54/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM113876; called by muse, mutect2, varscan2
- G6PD | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM952135; called by muse, mutect2, varscan2
- GPR156 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs146250011; called by muse, mutect2, varscan2
- GRM7 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 114/240 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63159463; called by muse, mutect2, varscan2
- KIAA2012 | c.2523del p.K841Nfs*2 | Frame Shift Del (DEL) | VAF 8/15 reads (53%) | catalogued as rs760609491; called by mutect2, varscan2
- MUC16 | c.12883G>A p.E4295K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs866967106, COSV67470836; called by muse, mutect2, varscan2
- PHF8 | c.1246C>T p.R416C (on ENST00000357988 / NM_001184896.1; = p.R380C on NM_015107.3) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV57683957; called by muse, mutect2, varscan2
- PRKAR2B | c.797T>C p.M266T | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs749115000; called by muse, mutect2, varscan2
- RHOG | c.481C>T p.Q161* | Nonsense Mutation (SNP) | VAF 138/318 reads (43%) | catalogued as COSV99544592; called by muse, mutect2, varscan2
- SI | c.3130G>A p.V1044I | Missense Mutation (SNP) | VAF 76/175 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1559993066; called by muse, mutect2, varscan2
- SPINK5 | c.494G>A p.R165Q | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs781071677; called by muse, mutect2, varscan2
- SPTBN5 | c.5399G>A p.R1800H | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs1006420452; called by muse, mutect2, varscan2
- TMEM199 | c.252A>C p.E84D | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV50228737; called by muse, mutect2, varscan2
- ULK4 | c.1967T>G p.F656C | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1340057882; called by muse, mutect2, varscan2
- ARHGAP10 | c.71C>T p.A24V | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- CD9 | c.169T>G p.Y57D | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CTAGE1 | c.1243A>T p.I415F | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- GCM1 | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- GPR156 | c.652T>C p.S218P | Missense Mutation (SNP) | VAF 75/181 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFFO1 | c.350G>A p.R117Q | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- IL12A | c.296C>A p.T99N | Missense Mutation (SNP) | VAF 64/160 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- IL18R1 | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 10/252 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- MAGEB16 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 54/143 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NTN5 | c.1216G>A p.D406N | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- PLCZ1 | c.1129A>C p.N377H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- RTTN | c.4198T>A p.C1400S | Missense Mutation (SNP) | VAF 64/149 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEMA3B | c.724del p.I242Sfs*10 | Frame Shift Del (DEL) | VAF 105/325 reads (32%) | called by mutect2, pindel, varscan2
- SETDB2 | c.736A>G p.I246V | Missense Mutation (SNP) | VAF 102/230 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- SLC9A3R2 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 52/105 reads (50%) | called by muse, mutect2, varscan2
- SLITRK3 | c.2689G>C p.V897L | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SMU1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 14/338 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.726); called by muse, mutect2
- VCAN | c.6488C>T p.T2163I | Missense Mutation (SNP) | VAF 39/87 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- ZNF382 | c.539A>T p.H180L | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- CACNG7 | c.42C>T p.S14= | Silent (SNP) | VAF 38/66 reads (58%) | catalogued as rs1214329802, COSV55815260; called by muse, mutect2, varscan2
- CCDC141 | c.3819G>A p.A1273= | Silent (SNP) | VAF 64/141 reads (45%) | catalogued as rs761543474, COSV55370461; called by muse, mutect2, varscan2
- CCND2 | c.15C>T p.C5= | Silent (SNP) | VAF 23/54 reads (43%) | catalogued as rs771959269, COSV99714180; called by muse, mutect2, varscan2
- DNAH7 | c.1608A>T p.I536= | Silent (SNP) | VAF 12/18 reads (67%) | called by muse, mutect2, varscan2
- HNRNPK | c.1353G>A p.L451= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as rs780132151, COSV61090407; called by muse, mutect2, varscan2
- LAMA4 | c.1485C>T p.A495= (on ENST00000230538 / NM_001105206.3; = p.A488= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1301840239; called by muse, mutect2, varscan2
- MAGEE2 | c.63C>T p.D21= | Silent (SNP) | VAF 67/150 reads (45%) | catalogued as rs753136353, COSV64897180; called by muse, mutect2, varscan2
- NPY1R | c.153C>T p.I51= | Silent (SNP) | VAF 13/289 reads (4%) | catalogued as COSV56713310, COSV99648723; called by muse, mutect2
- RCOR2 | c.501C>T p.P167= | Silent (SNP) | VAF 86/182 reads (47%) | called by muse, mutect2, varscan2
- SNPH | c.541C>T p.L181= | Silent (SNP) | VAF 45/115 reads (39%) | called by muse, mutect2, varscan2
- VPS13C | c.870A>C p.P290= (on ENST00000644861 / NM_020821.3; = p.P247= on NM_017684.5) | Silent (SNP) | VAF 35/68 reads (51%) | called by muse, varscan2
- AC079612.1 | n.892C>T | RNA (SNP) | VAF 64/153 reads (42%) | catalogued as rs556726351; called by muse, mutect2, varscan2
- ANKS1B | c.3672+7047G>A | Intron (SNP) | VAF 48/102 reads (47%) | catalogued as COSV100229113; called by muse, mutect2, varscan2
- BCLAF3 | chrX:19915160 C>A | 3'Flank (SNP) | VAF 48/113 reads (42%) | called by muse, mutect2, varscan2
- CDH10 | c.-103A>T | 5'UTR (SNP) | VAF 7/162 reads (4%) | called by muse, mutect2
- CDH6 | c.1882+338C>T | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as rs903541871; called by muse, mutect2, varscan2
- CEBPA | c.-86C>T | 5'UTR (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2, varscan2
- CTSA | c.444+101T>C | Intron (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- DNAAF1 | c.1644+27T>G | Intron (SNP) | VAF 49/111 reads (44%) | called by muse, mutect2, varscan2
- EML4 | c.*1037dup | 3'UTR (INS) | VAF 31/71 reads (44%) | catalogued as rs1443427145; called by mutect2, varscan2
- GPC4 | c.*1428G>T | 3'UTR (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- IGLL5 | c.-216T>C | 5'UTR (SNP) | VAF 28/70 reads (40%) | catalogued as COSV73250574; called by muse, mutect2, varscan2
- IGLL5 | c.-53C>T | 5'UTR (SNP) | VAF 34/83 reads (41%) | called by muse, mutect2, varscan2
- INF2 | c.701+109C>T | Intron (SNP) | VAF 10/27 reads (37%) | called by muse, mutect2, varscan2
- ISG20L2 | chr1:156728511 G>T | 5'Flank (SNP) | VAF 40/67 reads (60%) | called by muse, mutect2, varscan2
- KANK4 | c.*1030T>C | 3'UTR (SNP) | VAF 32/95 reads (34%) | catalogued as rs1197871652; called by muse, mutect2, varscan2
- KCNB1 | c.-72G>A | 5'UTR (SNP) | VAF 6/9 reads (67%) | called by muse, mutect2, varscan2
- MAGEB1 | c.*106G>T | 3'UTR (SNP) | VAF 10/41 reads (24%) | called by muse, mutect2, varscan2
- MIR4710 | chr14:104681332 A>G | 5'Flank (SNP) | VAF 56/134 reads (42%) | called by muse, mutect2, varscan2
- MOCOS | c.*376C>T | 3'UTR (SNP) | VAF 13/57 reads (23%) | called by muse, mutect2, varscan2
- MPP1 | c.1150-56_1150-37delinsTCACTTTCCTTTTCTTCCTT | Intron (ONP) | VAF 11/84 reads (13%) | called by pindel, varscan2*
- MYOG | c.*612G>T | 3'UTR (SNP) | VAF 41/88 reads (47%) | called by muse, mutect2, varscan2
- PAXBP1 | c.2268-59C>A | Intron (SNP) | VAF 18/35 reads (51%) | called by mutect2, varscan2
- PDZD4 | c.*379G>A | 3'UTR (SNP) | VAF 12/150 reads (8%) | called by muse, mutect2
- PGBD4 | c.*37del | 3'UTR (DEL) | VAF 125/331 reads (38%) | called by mutect2, pindel, varscan2
- PGM2L1 | c.*4351A>T | 3'UTR (SNP) | VAF 52/132 reads (39%) | called by muse, mutect2, varscan2
- PLPP6 | c.*621C>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | catalogued as rs1443474941, COSV99795149; called by muse, mutect2, varscan2
- PPP6C | c.-29C>T | 5'UTR (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- RAB11FIP2 | c.-156A>C | 5'UTR (SNP) | VAF 51/109 reads (47%) | called by muse, mutect2, varscan2
- RBM6 | c.2682+471C>T | Intron (SNP) | VAF 51/89 reads (57%) | called by muse, mutect2, varscan2
- RNF169 | c.*5240T>A | 3'UTR (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
- SEMA3E | c.*2211C>A | 3'UTR (SNP) | VAF 9/38 reads (24%) | catalogued as rs1211143228; called by muse, mutect2, varscan2
- SH2D1B | c.*1540A>G | 3'UTR (SNP) | VAF 72/151 reads (48%) | catalogued as rs896568313; called by muse, mutect2, varscan2
- SLC44A1 | c.*496A>T | 3'UTR (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- SLFN11 | c.*1333T>A | 3'UTR (SNP) | VAF 15/44 reads (34%) | called by muse, mutect2, varscan2
- SPIDR | c.*379T>G | 3'UTR (SNP) | VAF 36/108 reads (33%) | called by muse, mutect2, varscan2
- SPOCK2 | c.*361T>C | 3'UTR (SNP) | VAF 30/63 reads (48%) | called by muse, mutect2, varscan2
- TP63 | c.-104T>C | 5'UTR (SNP) | VAF 84/198 reads (42%) | called by muse, mutect2
- TRIM77BP | n.261C>A | RNA (SNP) | VAF 77/147 reads (52%) | called by muse, mutect2, varscan2
- TTN | c.10360+3794G>A | Intron (SNP) | VAF 29/192 reads (15%) | called by muse, mutect2, varscan2
- ZNF33A | c.*70A>G | 3'UTR (SNP) | VAF 123/277 reads (44%) | catalogued as rs1328157426; called by muse, mutect2, varscan2
